Somatic mutation profile of tumor specimen TCGA-28-1751-01A (aliquot TCGA-28-1751-01A-02W-0643-08) from TCGA case TCGA-28-1751, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.0 years (22,291 days).
Specimen TCGA-28-1751-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a51f505-77c0-47de-b9e5-1e2e62f4fc33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-1751-10A (Blood Derived Normal), aliquot TCGA-28-1751-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0507efd4-0190-4a86-a47c-9c9b724505d5

The open-access MAF lists 60 somatic variants for this specimen: 40 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 19, Frame Shift Ins 3, Frame Shift Del 2, Nonsense Mutation 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.854T>C p.F285S | Missense Mutation (SNP) | VAF 28/233 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918463, CM021134, CM060447, COSV61005134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAT | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100528739; called by muse, mutect2
- ADGRG2 | c.991C>T p.Q331* (on ENST00000379869 / NM_001079858.3; = p.Q328* on NM_005756.4) | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100492796; called by muse, mutect2, varscan2
- AKAP13 | c.3649C>T p.R1217* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as rs777358897, COSV100774825; called by mutect2, varscan2
- CACNG3 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248441351, COSV50064358; called by muse, mutect2
- CIITA | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.013); catalogued as rs756879407, COSV60859384; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DGKD | c.2203G>A p.G735S (on ENST00000264057 / NM_152879.3; = p.G691S on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV99897791; called by muse, mutect2, varscan2
- DNAJB8 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs112059249, COSV59878472; called by muse, mutect2, varscan2
- EXOC3L4 | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV101197588, COSV101197741; called by muse, mutect2, varscan2
- FNIP1 | c.2654G>A p.C885Y | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.904); catalogued as COSV100330641, COSV57196943; called by muse, mutect2
- GSTO2 | c.685C>A p.L229I | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV100086879, COSV58537924; called by muse, mutect2
- IDE | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99794488; called by muse, mutect2
- IFIT3 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as COSV99261080; called by muse, mutect2
- ITGA3 | c.1450C>T p.L484F | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1307875890, COSV99144373; called by muse, mutect2, varscan2
- KLF17 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100955044, COSV64856736; called by muse, mutect2, varscan2
- MAGED2 | c.710G>T p.W237L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as COSV99514800; called by muse, mutect2, varscan2
- NEK8 | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 80/406 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs373048342; called by mutect2, varscan2
- OR10S1 | c.234C>G p.H78Q | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV101602510, COSV73342719; called by muse, mutect2
- OR12D2 | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 9/221 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV101011505; called by muse, mutect2
- OR2T35 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 92/147 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407670092; called by muse, mutect2, varscan2
- OSBPL9 | c.290C>G p.T97R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100544163; called by muse, mutect2, varscan2
- PRICKLE2 | c.1253C>T p.S418F (on ENST00000295902; = p.S362F on NM_198859.4) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.622); catalogued as COSV55765318; called by mutect2, varscan2
- RELN | c.4307C>A p.A1436E | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100635069; called by muse, mutect2
- RGS7 | c.1139G>T p.R380I | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100471511; called by muse, mutect2
- SERPINB4 | c.862A>C p.K288Q | Missense Mutation (SNP) | VAF 92/456 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.919); catalogued as COSV100346032; called by muse, mutect2, varscan2
- SH3PXD2A | c.328dup p.H110Pfs*6 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | catalogued as rs777796332; called by mutect2, varscan2
- SIPA1L3 | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 160/252 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV55910336; called by muse, mutect2, varscan2
- SLC44A2 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs200371616; called by muse, mutect2
- SLC4A2 | c.2552C>T p.P851L | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99879427; called by mutect2, varscan2
- TAF1 | c.4845C>A p.D1615E (on ENST00000373790 / NM_138923.4; = p.D1636E on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV99337245; called by muse, mutect2, varscan2
- TASOR2 | c.6320A>G p.D2107G | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.351); catalogued as COSV100051186; called by muse, mutect2
- TFAP2D | c.692T>C p.I231T | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV99148208; called by muse, mutect2, varscan2
- VCL | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99281371; called by muse, varscan2
- WFDC5 | c.98dup p.C34Lfs*5 | Frame Shift Ins (INS) | VAF 4/43 reads (9%) | catalogued as rs767342014; called by pindel, varscan2
- WWC1 | c.766C>T p.H256Y | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV99514723; called by muse, mutect2, varscan2
- ZNF229 | c.2390C>T p.T797M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs778421395, COSV52161234; called by muse, mutect2, varscan2
- GRHL3 | c.254del p.D85Afs*26 (on ENST00000350501 / NM_198174.3; = p.D90Afs*26 on NM_021180.3) | Frame Shift Del (DEL) | VAF 12/101 reads (12%) | called by mutect2, pindel, varscan2
- PKHD1 | c.5031C>G p.I1677M | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by mutect2, varscan2
- PLPPR4 | c.617_620del p.Y206Ffs*2 | Frame Shift Del (DEL) | VAF 24/110 reads (22%) | called by mutect2, pindel, varscan2
- POFUT2 | c.158dup p.E54Gfs*43 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- ABCC1 | c.3441C>T p.S1147= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV60695431; called by muse, mutect2, varscan2
- CALHM5 | c.418C>T p.L140= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV62067725; called by muse, mutect2
- CEACAM19 | c.306C>T p.F102= | Silent (SNP) | VAF 50/87 reads (57%) | catalogued as COSV100715529, COSV62551876; called by muse, mutect2, varscan2
- ERBB4 | c.963A>G p.K321= | Silent (SNP) | VAF 68/141 reads (48%) | catalogued as COSV53504167, COSV99634927; called by muse, mutect2, varscan2
- HCAR1 | c.300C>T p.A100= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as rs375274291; called by muse, varscan2
- HGD | c.1257G>A p.L419= | Silent (SNP) | VAF 90/519 reads (17%) | catalogued as COSV99381489; called by muse, mutect2, varscan2
- IFNK | c.498C>T p.F166= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99219058; called by muse, mutect2, varscan2
- KCNH5 | c.1641A>G p.E547= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as COSV100528418, COSV59761083; called by muse, mutect2
- KIR2DL3 | c.381G>A p.E127= | Silent (SNP) | VAF 28/856 reads (3%) | catalogued as COSV100668138, COSV60901414; called by muse, mutect2
- KLK4 | c.471G>T p.A157= | Silent (SNP) | VAF 6/120 reads (5%) | catalogued as COSV100133735; called by muse, mutect2
- MPEG1 | c.1836G>A p.V612= | Silent (SNP) | VAF 22/375 reads (6%) | catalogued as rs745774320, COSV99916033; called by muse, mutect2
- MYH2 | c.4545T>A p.I1515= | Silent (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- NDST4 | c.1173C>T p.N391= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs767761210, COSV52127639; called by muse, mutect2, varscan2
- OR51E2 | c.607C>T p.L203= | Silent (SNP) | VAF 30/202 reads (15%) | catalogued as COSV101211410; called by muse, mutect2, varscan2
- OSR1 | c.546C>A p.R182= | Silent (SNP) | VAF 9/151 reads (6%) | catalogued as COSV99693869; called by muse, mutect2
- RUSC2 | c.897C>A p.L299= | Silent (SNP) | VAF 11/116 reads (9%) | catalogued as COSV100770936, COSV63430238; called by muse, mutect2
- STAU1 | c.868C>A p.R290= (on ENST00000371856 / NM_001319135.1; = p.R209= on NM_004602.3) | Silent (SNP) | VAF 25/360 reads (7%) | catalogued as COSV100574631, COSV61460121; called by muse, mutect2
- SYTL3 | c.825C>T p.P275= (on ENST00000611299 / NM_001242394.1; = p.P207= on NM_001009991.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/592 reads (11%) | catalogued as COSV99792695; called by muse, mutect2, varscan2
- ZNF337 | c.1767C>T p.F589= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV99430536; called by muse, mutect2
- DUOXA1 | chr15:45117795 C>A | 3'Flank (SNP) | VAF 8/146 reads (5%) | catalogued as COSV99973620; called by muse, mutect2
